Gene-level copy-number profile of tumor specimen TCGA-26-5132-01A from TCGA case TCGA-26-5132, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.5 years (27,196 days).
Specimen TCGA-26-5132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.136994a2-c5fb-4eaf-b03e-07727be72448.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,953 have no estimate.
https://portal.gdc.cancer.gov/files/3c136fa9-2f65-419a-abe3-6adc2b6392e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,699; copy number 2: 45,904; copy number 3: 2,942; copy number 4: 44; copy number 6: 9; copy number 7: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-26-5132-01A-01D-1479-01): tumor purity 0.89, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 81 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:53,655,508–56,080,670, 58 genes, copy number 7 (within-gene range 3–7): LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2.
- chr12:4,269,771–4,538,508, 7 genes, copy number 6 (within-gene range 1–6): CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4.
- chr12:39,293,228–39,448,314, 2 genes, copy number 6 (within-gene range 1–6): KIF21A, AC121334.4.
- chr12:71,439,798–71,835,396, 12 genes, copy number 7: LGR5, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2.
- chr12:101,646,720–101,696,450, 2 genes, copy number 7 (within-gene range 2–7): AC117505.1, AC010205.1.

Autosomal genes at a single copy (total copy number 1): 6,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
